TARGET case TARGET-40-PATMPU — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/820f8091-cb06-55d0-bf7e-c101bb984e7a

Demographics
Sex at birth: male; Age at index: 13 years; Vital status: Dead; Days to death: 1,579 days (4.3 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Classification of tumor: primary; Age at diagnosis: 13.9 years (5,060 days); Year of diagnosis: 2010; Metastasis at diagnosis: No Metastasis; Days to last follow up: 1,579 days (4.3 years).
   Treatment given: Protocol identifier: AOST0331.

Follow-up (2 entries)
- Days to follow up: 498 days (1.4 years); Progression or recurrence: Yes; Days to progression: 498 days (1.4 years); Days to first event: 498 days (1.4 years); First event: Relapse.
- Days to follow up: 1,579 days (4.3 years); Year of follow up: 2014.

Biospecimens (2 samples)
- Sample TARGET-40-PATMPU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-PATMPU-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_20230709.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1579
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Leg/foot
- Specific tumor site: Fibula
- Specific tumor region: Proximal
- Definitive Surgery: Limb sparing
- Primary site progression: No
- Site of initial relapse: Non-bone, non-lung
- Histologic response: Stage 1/2 (0-90 % necrosis)

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-PATMPU-01A-01:
- Specimen Type: Frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 98
- % Non Tumor Nuclei: Top from Biopsy: 2
- % Cellular Tumor: Top from Biopsy: 90
- % Normal: Top from Biopsy: 0
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 10
- PASS/FAIL: PASS
